Gene-level copy-number profile of tumor specimen C3N-00314-04 from CPTAC case C3N-00314, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 79.0 years (28,865 days).
Specimen C3N-00314-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bed0c5e5-6074-47b1-a0cc-347547c676d4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00314-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/08cb5025-059e-4526-902a-5a6b66c67fbb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,604; copy number 1: 2,900; copy number 2: 48,879; copy number 3: 23; copy number 4: 3,496; copy number 5: 11; copy number 6: 1; copy number 9: 1.

Caution: 3,600 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 3,600 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–90,261,708, 1,347 genes (broad region; genes not listed).
- chr9:12,134–138,253,217, 2,253 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–133,723, 11 genes, copy number 5 (within-gene range 2–5): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3.

Autosomal genes at a single copy (total copy number 1): 54. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
